Somatic mutation profile of tumor specimen TCGA-CR-7383-01A (aliquot TCGA-CR-7383-01A-11D-2129-08) from TCGA case TCGA-CR-7383, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.7 years (29,122 days).
Specimen TCGA-CR-7383-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5985398d-20e4-42e0-b6c5-1628887226ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7383-10A (Blood Derived Normal), aliquot TCGA-CR-7383-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3baec957-cf12-4119-ac8d-28dfec033b40

The open-access MAF lists 125 somatic variants for this specimen: 96 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 26, Nonsense Mutation 9, RNA 3, Splice Site 2, Splice Region 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 38/114 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- SMARCA4 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs797045981, COSV100758931, COSV60787151; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 71/146 reads (49%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.3494A>G p.N1165S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933175; called by muse, mutect2
- AC018630.4 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | PolyPhen possibly damaging (0.452); catalogued as COSV101115247; called by muse, mutect2, varscan2
- ACOT13 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1166320019, COSV100016066; called by muse, mutect2, varscan2
- ADCY8 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763633456, COSV53917295; called by muse, mutect2, varscan2
- BRIP1 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764061653, COSV99370644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSPRY | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.335); catalogued as COSV100949552; called by muse, mutect2, varscan2
- CAMSAP2 | c.2563C>T p.P855S (on ENST00000236925 / NM_001297707.2; = p.P844S on NM_203459.3) | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766404871, COSV99373838; called by muse, mutect2, varscan2
- CNOT8 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53585676; called by muse, mutect2, varscan2
- DAGLA | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as rs754503469, COSV99944585; called by muse, mutect2, varscan2
- DDC | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 91/277 reads (33%) | catalogued as COSV100779638; called by muse, mutect2, varscan2
- DISC1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV99698292; called by muse, mutect2, varscan2
- ECM2 | c.397T>A p.C133S | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100755947; called by muse, mutect2, varscan2
- EIF5B | c.3092A>G p.Y1031C | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766979068, COSV99177582; called by muse, mutect2, varscan2
- EXPH5 | c.5876A>G p.Y1959C | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1297992256, COSV99761960; called by muse, mutect2, varscan2
- FAM222B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745936897, COSV100368622; called by muse, varscan2
- FARP2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs762659865, COSV99885108; called by muse, mutect2, varscan2
- FAT2 | c.8588T>C p.L2863P | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753051338, COSV55814894; called by muse, mutect2, varscan2
- FAXDC2 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170487484, COSV100303959; called by muse, mutect2, varscan2
- FLT1 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs372046832, COSV56729596; called by muse, mutect2, varscan2
- FSTL5 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100058735, COSV100059758; called by muse, mutect2, varscan2
- FXYD5 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 98/574 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779297539, COSV61569465; called by muse, mutect2, varscan2
- GLDC | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as COSV100394373; called by muse, mutect2, varscan2
- GPC5 | c.1364T>C p.I455T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100995039; called by muse, mutect2, varscan2
- GPRC6A | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368860950, COSV59956215; called by muse, mutect2, varscan2
- GRIN2B | c.1043A>C p.N348T | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101663125; called by muse, mutect2, varscan2
- GSKIP | c.261G>A p.V87= | Splice Region (SNP) | VAF 40/203 reads (20%) | catalogued as COSV101347625; called by muse, mutect2, varscan2
- HHATL | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as rs140686107; called by muse, mutect2, varscan2
- HNF1A | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as CM082879, COSV99982817; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100079744; called by muse, mutect2
- HPSE | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100264461; called by muse, mutect2, varscan2
- HRH4 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV99907943, COSV99907994; called by muse, mutect2, varscan2
- HTR5A | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs780879819, COSV99839524; called by muse, mutect2, varscan2
- IPO9 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100843509; called by muse, mutect2, varscan2
- KHDRBS2 | c.1018G>C p.G340R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.245); catalogued as rs139583671; called by muse, mutect2, varscan2
- KMT2C | c.7498G>A p.V2500M | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100074644; called by muse, mutect2, varscan2
- LCK | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100287914; called by muse, mutect2, varscan2
- LILRA4 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV52495602; called by muse, mutect2, varscan2
- LIPE | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99734301; called by muse, mutect2, varscan2
- LRP1 | c.12190G>T p.A4064S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs1401127073, COSV54504777, COSV99676621; called by muse, mutect2, varscan2
- LRRK2 | c.2618A>T p.D873V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs1270648624, COSV100110844; called by muse, mutect2, varscan2
- LYG2 | c.72T>G p.S24R | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100283730; called by muse, mutect2, varscan2
- MAPT | c.860C>T p.P287L (on ENST00000262410 / NM_001377265.1; = p.P212L on NM_016835.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as rs368295974; called by muse, mutect2, varscan2
- MYCT1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 56/214 reads (26%) | catalogued as rs371983005; called by muse, mutect2, varscan2
- NBAS | c.5491C>T p.P1831S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99870966; called by muse, mutect2, varscan2
- NPFFR2 | c.1007T>A p.L336H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100441036; called by muse, mutect2, varscan2
- NRDE2 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100583581; called by muse, mutect2, varscan2
- OLFM4 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99524484; called by muse, mutect2, varscan2
- OPA1 | c.770A>G p.Y257C (on ENST00000361510 / NM_130837.3; = p.Y221C on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV100655406; called by muse, mutect2, varscan2
- OR2G6 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs373436860; called by muse, mutect2, varscan2
- OR2T12 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs771048088, COSV58775783; called by muse, mutect2, varscan2
- OR2T4 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100822550; called by muse, mutect2, varscan2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>T p.E1443* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100868379, COSV62798918; called by muse, mutect2, varscan2
- PCDHGB2 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as rs1174960250, COSV53984178; called by muse, mutect2, varscan2
- PKN2 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1391923175, COSV100981403; called by muse, mutect2, varscan2
- PLEC | c.4303T>A p.S1435T (on ENST00000322810 / NM_201380.4; = p.S1325T on NM_000445.5) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100516821; called by muse, mutect2, varscan2
- PMAIP1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504892; called by muse, mutect2, varscan2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 104/416 reads (25%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2, varscan2
- PTCH2 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs200862802; called by muse, mutect2, varscan2
- PTGER2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1417333554, COSV99817612; called by muse, mutect2, varscan2
- PWWP2B | c.1275C>G p.S425R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs766724858, COSV100535892; called by muse, mutect2, varscan2
- RTEL1 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV99423189; called by muse, mutect2, varscan2
- RTN4RL1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100486701, COSV58674793; called by muse, mutect2, varscan2
- SCYL2 | c.1860G>A p.Q620= | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100675276; called by muse, mutect2, varscan2
- SIPA1 | c.2845G>T p.E949* | Nonsense Mutation (SNP) | VAF 45/182 reads (25%) | catalogued as COSV100425882; called by muse, mutect2, varscan2
- SLC13A2 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100120429; called by muse, mutect2, varscan2
- SLC25A32 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.315); catalogued as rs1224476212, COSV99884601; called by muse, mutect2, varscan2
- SLC26A7 | c.1281A>T p.L427F | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562708766, COSV99403944; called by muse, mutect2
- SMPDL3A | c.1053G>T p.L351F | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100868720; called by muse, mutect2, varscan2
- SNRPD2 | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as COSV99171303; called by muse, mutect2, varscan2
- SORCS1 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV99548553; called by muse, mutect2, varscan2
- SRRT | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV100730275; called by muse, mutect2, varscan2
- ST18 | c.2016T>A p.Y672* | Nonsense Mutation (SNP) | VAF 8/93 reads (9%) | catalogued as COSV99390503; called by muse, mutect2
- STYXL2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1002949988, COSV99609590; called by muse, mutect2
- TCEAL2 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100216363; called by muse, mutect2, varscan2
- TMEM54 | c.17-2A>T p.X6_splice | Splice Site (SNP) | VAF 35/110 reads (32%) | catalogued as COSV100231976; called by muse, mutect2, varscan2
- TNK2 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.113); catalogued as COSV100361535; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100836162; called by muse, mutect2, varscan2
- TNMD | c.468G>C p.W156C | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100887898; called by muse, mutect2, varscan2
- TRAPPC6A | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as COSV99135346; called by muse, mutect2, varscan2
- TRIP10 | c.1304C>T p.P435L (on ENST00000313244 / NM_001288962.2; = p.P379L on NM_004240.4) | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99838129; called by muse, mutect2, varscan2
- TUBA1B | c.865G>C p.A289P | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV100254189; called by muse, mutect2, varscan2
- VPS13B | c.2787C>G p.I929M | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100662806, COSV62144985; called by muse, mutect2, varscan2
- XIRP2 | c.3247G>A p.D1083N (on ENST00000628543; = p.D1258N on NM_152381.6) | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV54698135; called by muse, mutect2
- XKRX | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 163/438 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100139756; called by muse, mutect2, varscan2
- ZBTB7A | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV100475823; called by muse, mutect2, varscan2
- ZIC4 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101268078, COSV67172954; called by muse, mutect2, varscan2
- ZNF461 | c.1649T>A p.V550D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV100831451; called by muse, mutect2
- ACACA | c.2924G>A p.S975N | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNPAT | c.337_339del p.K113del | In Frame Del (DEL) | VAF 58/586 reads (10%) | called by mutect2, pindel, varscan2
- OPHN1 | c.524dup p.E176Rfs*5 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by pindel, varscan2
- TRBC2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- TTN | c.100494del p.V33499Sfs*21 (on ENST00000591111; = p.V26075Sfs*21 on NM_003319.4) | Frame Shift Del (DEL) | VAF 72/439 reads (16%) | called by mutect2, pindel, varscan2
- ACRBP | c.606G>A p.E202= | Silent (SNP) | VAF 44/246 reads (18%) | catalogued as COSV99976226; called by muse, mutect2, varscan2
- BRWD1 | c.972C>T p.G324= | Silent (SNP) | VAF 52/183 reads (28%) | catalogued as rs768846491, COSV100313343; called by muse, mutect2, varscan2
- CCDC151 | c.645G>A p.K215= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs765297835, COSV100710592; called by muse, mutect2, varscan2
- CHAF1B | c.1602C>T p.D534= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs749390019, COSV58441513; called by muse, mutect2, varscan2
- COL4A5 | c.3546T>C p.G1182= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100088871; called by muse, mutect2, varscan2
- DDX39A | c.711G>T p.V237= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV99660409; called by muse, mutect2, varscan2
- EZHIP | c.195C>T p.A65= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100539811; called by muse, mutect2, varscan2
- HELZ | c.4659G>A p.P1553= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as rs368464329; called by muse, mutect2
- ITGB4 | c.718C>T p.L240= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99564421; called by muse, mutect2, varscan2
- KAT2B | c.225C>T p.I75= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99769640; called by muse, mutect2, varscan2
- KLHL24 | c.939G>A p.E313= | Silent (SNP) | VAF 51/219 reads (23%) | catalogued as COSV99665069; called by muse, mutect2, varscan2
- LGMN | c.1015C>T p.L339= | Silent (SNP) | VAF 73/341 reads (21%) | catalogued as COSV58404250; called by muse, mutect2, varscan2
- MC1R | c.498G>A p.A166= | Silent (SNP) | VAF 35/200 reads (18%) | catalogued as rs374959395; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC3A | c.9036G>A p.V3012= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as COSV100115064; called by muse, mutect2
- MYO10 | c.4959G>A p.L1653= | Silent (SNP) | VAF 34/350 reads (10%) | catalogued as COSV99945918; called by muse, mutect2
- N4BP2L2 | c.1737C>A p.V579= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV99912644; called by muse, mutect2, varscan2
- PCDHA12 | c.270C>A p.I90= | Silent (SNP) | VAF 72/532 reads (14%) | catalogued as COSV100252533, COSV56480091; called by muse, varscan2
- POF1B | c.819C>T p.H273= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs1479726194, COSV99427094; called by muse, mutect2, varscan2
- PRB2 | c.1086T>C p.P362= | Silent (SNP) | VAF 147/780 reads (19%) | catalogued as COSV101231465; called by muse, mutect2, varscan2
- PTPN22 | c.609C>T p.D203= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as COSV100703831; called by muse, mutect2, varscan2
- RAD51AP2 | c.2139T>C p.C713= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV67589340; called by muse, mutect2, varscan2
- RSPH14 | c.618C>T p.I206= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV99321032; called by muse, mutect2
- RUNX2 | c.783C>A p.V261= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as COSV100767615; called by muse, mutect2
- STEAP2 | c.1302T>G p.L434= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99840568; called by muse, mutect2, varscan2
- TACSTD2 | c.327C>T p.D109= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100973756; called by muse, mutect2, varscan2
- ZNF670 | c.426T>C p.H142= | Silent (SNP) | VAF 82/293 reads (28%) | catalogued as COSV100829314; called by muse, mutect2, varscan2
- AL590867.2 | n.107G>A | RNA (SNP) | VAF 82/320 reads (26%) | called by muse, mutect2, varscan2
- OR2U1P | n.611T>C | RNA (SNP) | VAF 10/75 reads (13%) | catalogued as rs1474863055; called by muse, mutect2, varscan2
- SNORD115-12 | n.66G>T | RNA (SNP) | VAF 99/794 reads (12%) | called by muse, mutect2, varscan2
